Somatic mutation profile of tumor specimen TCGA-GL-A9DD-01A (aliquot TCGA-GL-A9DD-01A-11D-A36X-10) from TCGA case TCGA-GL-A9DD, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.8 years (25,483 days).
Specimen TCGA-GL-A9DD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a3a6dc4-407a-4c92-a06c-e8ddb74b1a1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GL-A9DD-10A (Blood Derived Normal), aliquot TCGA-GL-A9DD-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a44546c-6c26-47c0-90dd-912d870d210b

The open-access MAF lists 104 somatic variants for this specimen: 81 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 55, Silent 23, Frame Shift Del 12, Frame Shift Ins 4, Nonsense Mutation 4, Splice Site 3, In Frame Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LMNA | c.936+1G>A p.X312_splice | Splice Site (SNP) | VAF 34/161 reads (21%) | catalogued as rs267607588, CD132954, HS050003, COSV100738532; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACADL | c.1151T>C p.V384A | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV99284563; called by muse, mutect2, varscan2
- ADCY7 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs777789294, COSV99575724; called by muse, mutect2, varscan2
- ARMC9 | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs1284553911, COSV100589532; called by muse, mutect2, varscan2
- ASGR2 | c.313T>A p.S105T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV99642890; called by muse, mutect2, varscan2
- C21orf62 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377322005; called by muse, mutect2, varscan2
- CCDC115 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418691405, COSV99383620; called by muse, mutect2, varscan2
- CCDC116 | c.1384G>C p.G462R | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53042061, COSV99489151; called by muse, mutect2, varscan2
- CEACAM3 | c.532A>G p.K178E | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs191651318, COSV99704865; called by muse, mutect2, varscan2
- CROCC | c.409del p.L137Wfs*70 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs1557583809; called by mutect2, pindel, varscan2
- CS | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV100673161; called by muse, mutect2, varscan2
- CYP39A1 | c.706T>G p.C236G | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV51496996, COSV99241920; called by muse, mutect2, varscan2
- DDX21 | c.1731A>C p.K577N | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV100826476; called by muse, mutect2, varscan2
- DDX24 | c.1350A>C p.E450D | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.208); catalogued as COSV100427832; called by muse, mutect2, varscan2
- DNAH7 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100414098; called by muse, mutect2, varscan2
- DROSHA | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as COSV100757499; called by muse, mutect2, varscan2
- FAM151A | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as rs1445721854, COSV100156765; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1485A>T p.K495N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV99734116; called by muse, mutect2, varscan2
- HTR3D | c.1310_1311insT p.L438Pfs*55 (on ENST00000382489 / NM_001163646.2; = p.L263Pfs*55 on NM_182537.3) | Frame Shift Ins (INS) | VAF 28/129 reads (22%) | catalogued as COSV100487928; called by mutect2, pindel, varscan2
- IGBP1P2 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 71/222 reads (32%) | catalogued as rs201341730; called by muse, mutect2, varscan2
- ILVBL | c.1435G>C p.V479L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.066); catalogued as COSV99654610; called by muse, mutect2, varscan2
- IQGAP3 | c.2739+1G>T p.X913_splice | Splice Site (SNP) | VAF 9/56 reads (16%) | catalogued as rs1403935355, COSV100752085; called by muse, mutect2, varscan2
- IRS2 | c.773A>T p.E258V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101018853; called by muse, mutect2, varscan2
- JMJD1C | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1396873817, COSV101232225; called by muse, mutect2, varscan2
- KATNA1 | c.455T>A p.V152D | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as COSV100167661; called by muse, mutect2, varscan2
- LRP1B | c.4064A>T p.N1355I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101253519; called by muse, mutect2, varscan2
- LSM8 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50800414, COSV99972724; called by muse, mutect2, varscan2
- MAN2B2 | c.35C>A p.P12Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99577017; called by muse, mutect2, varscan2
- MAP3K15 | c.3323T>G p.I1108S | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV100134220; called by muse, mutect2, varscan2
- MAPKAP1 | c.671A>G p.N224S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.08); catalogued as COSV99784418; called by muse, mutect2, varscan2
- MDN1 | c.9507C>A p.S3169R | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101020839; called by muse, mutect2, varscan2
- METTL3 | c.1056G>C p.E352D | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99398041; called by muse, mutect2, varscan2
- MFN2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99336549; called by muse, mutect2, varscan2
- MGAM | c.538T>A p.S180T | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV101516353; called by muse, mutect2, varscan2
- MTCH1 | c.1117T>G p.S373A (on ENST00000373627 / NM_001271641.1; = p.S356A on NM_014341.2) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as COSV101010156; called by muse, mutect2, varscan2
- NOBOX | c.734C>G p.A245G | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV99779267; called by muse, mutect2, varscan2
- NR2F6 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99285634; called by muse, mutect2, varscan2
- PARD3B | c.2180A>T p.K727I | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV100592306; called by muse, mutect2, varscan2
- PCDHGC3 | c.2084T>G p.L695R | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99338415; called by muse, mutect2, varscan2
- PCNX1 | c.4492T>A p.S1498T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs1354664162, COSV99454359; called by muse, mutect2, varscan2
- PGLYRP2 | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV99483804; called by muse, mutect2, varscan2
- PIK3C2A | c.4582T>G p.C1528G | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as rs1398999204, COSV99790318; called by muse, mutect2, varscan2
- PIP4K2A | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100114388; called by muse, mutect2, varscan2
- PLEC | c.5233G>A p.E1745K (on ENST00000322810 / NM_201380.4; = p.E1635K on NM_000445.5) | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.297); catalogued as COSV100511525; called by muse, mutect2, varscan2
- POU3F2 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.986); catalogued as COSV100098993; called by muse, mutect2
- PSIP1 | c.894C>A p.H298Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101050898; called by muse, mutect2, varscan2
- PTPRD | c.5033T>G p.I1678S | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100643657; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.642G>A p.W214* | Nonsense Mutation (SNP) | VAF 47/244 reads (19%) | catalogued as COSV101208246; called by muse, mutect2, varscan2
- RINT1 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV99994240; called by muse, mutect2, varscan2
- RSAD2 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1393647190, COSV101149777; called by muse, mutect2, varscan2
- SEC31A | c.3065C>A p.S1022* (on ENST00000355196 / NM_001318120.1; = p.S983* on NM_016211.4) | Nonsense Mutation (SNP) | VAF 29/150 reads (19%) | catalogued as COSV100021622; called by muse, mutect2, varscan2
- SENP5 | c.949A>T p.K317* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100051820; called by muse, mutect2, varscan2
- SGPP1 | c.422A>T p.E141V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99905725; called by muse, mutect2, varscan2
- SNAPC4 | c.130+1G>T p.X44_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100046868, COSV53738866; called by muse, mutect2, varscan2
- SRSF4 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100861365; called by muse, mutect2, varscan2
- SRSF7 | c.94A>G p.S32G | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV100492543, COSV57446635; called by muse, varscan2
- TEX10 | c.2404T>C p.Y802H | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV100887614; called by muse, mutect2, varscan2
- TMTC2 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100337611; called by muse, mutect2, varscan2
- TNFRSF10D | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.799); catalogued as COSV100441620; called by muse, mutect2, varscan2
- TUT4 | c.714T>G p.D238E | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV99931893; called by mutect2, varscan2
- WDR36 | c.1936A>T p.I646F | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV101550950, COSV72605185; called by muse, mutect2, varscan2
- ZNF479 | c.1202G>C p.R401T | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.291); catalogued as COSV100482551, COSV100482558; called by muse, mutect2, varscan2
- ZNF611 | c.1982G>T p.R661L | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.194); catalogued as COSV100159971, COSV100160068; called by muse, mutect2, varscan2
- ZNF786 | c.2347T>G p.*783Gext*9 | Nonstop Mutation (SNP) | VAF 32/87 reads (37%) | catalogued as COSV60275147; called by muse, mutect2, varscan2
- ZNF91 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs1329185372, COSV100322264; called by muse, mutect2, varscan2
- ADCY6 | c.941_943del p.Q314del | In Frame Del (DEL) | VAF 54/151 reads (36%) | called by mutect2, pindel, varscan2
- ARHGAP24 | c.1704dup p.N569Qfs*21 (on ENST00000395184 / NM_001025616.3; = p.N476Qfs*21 on NM_031305.3) | Frame Shift Ins (INS) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- C3orf22 | c.139del p.V47Sfs*60 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- DIDO1 | c.2104dup p.I702Nfs*6 | Frame Shift Ins (INS) | VAF 27/119 reads (23%) | called by mutect2, pindel, varscan2
- FAT1 | c.1389dup p.T464Yfs*10 | Frame Shift Ins (INS) | VAF 25/105 reads (24%) | called by mutect2, pindel, varscan2
- FOXJ1 | c.178del p.H60Tfs*61 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- KMT2C | c.11604del p.K3870Rfs*19 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel, varscan2
- KSR1 | c.1277del p.L426Pfs*5 (on ENST00000644974 / NM_001367810.1; = p.L289Pfs*5 on NM_014238.2) | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- SGSM1 | c.705_711del p.R236Pfs*50 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- SIMC1 | c.2455_2465del p.E819* (on ENST00000443967 / NM_001308196.1; = p.E404* on NM_198567.5) | Frame Shift Del (DEL) | VAF 36/191 reads (19%) | called by mutect2, pindel, varscan2
- TLR1 | c.21del p.F7Lfs*7 | Frame Shift Del (DEL) | VAF 66/322 reads (20%) | called by mutect2, pindel, varscan2
- TRIP11 | c.4444_4452del p.L1482_E1484del | In Frame Del (DEL) | VAF 16/102 reads (16%) | called by mutect2, pindel, varscan2
- TSR1 | c.637_643del p.K213Ffs*9 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | called by pindel, varscan2
- ZBTB40 | c.1677del p.A560Pfs*8 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- ZNF627 | c.747del p.K249Nfs*68 | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | called by mutect2, pindel, varscan2
- ZNF628 | c.400_401delinsT p.H134Sfs*6 | Frame Shift Del (DEL) | VAF 19/106 reads (18%) | called by pindel, varscan2*
- AK9 | c.1089C>A p.I363= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV53423720, COSV53424140; called by muse, mutect2, varscan2
- ALG3 | c.405C>G p.T135= | Silent (SNP) | VAF 44/155 reads (28%) | catalogued as COSV99890811, COSV99891268; called by muse, mutect2, varscan2
- AOC1 | c.1386T>C p.D462= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs1194658116, COSV100710633; called by muse, mutect2, varscan2
- ASH1L | c.2932T>C p.L978= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100853165; called by muse, mutect2, varscan2
- CLASRP | c.138A>C p.R46= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99673579; called by muse, mutect2, varscan2
- COL5A2 | c.2817A>T p.G939= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV100880041; called by muse, mutect2, varscan2
- CPN1 | c.1332A>G p.R444= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100962560; called by muse, mutect2, varscan2
- FNBP4 | c.2367A>C p.I789= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV99771465; called by muse, mutect2, varscan2
- HENMT1 | c.609C>T p.Y203= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100898639; called by muse, mutect2, varscan2
- MOGAT3 | c.93C>T p.L31= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs767938339, COSV99777032; called by muse, mutect2, varscan2
- NMD3 | c.1261T>C p.L421= | Silent (SNP) | VAF 54/316 reads (17%) | catalogued as rs1220396506, COSV100664618; called by muse, mutect2, varscan2
- ROBO1 | c.2298G>A p.K766= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as rs536774102, COSV101458336; called by muse, mutect2, varscan2
- RPL7A | c.69G>A p.E23= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs1260268841, COSV100034568; called by muse, mutect2, varscan2
- SELENOI | c.72T>C p.D24= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99564247; called by muse, mutect2, varscan2
- SLC8A1 | c.9C>T p.N3= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs758825513, COSV100244818; called by muse, mutect2, varscan2
- SPON2 | c.210T>A p.S70= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV99335121; called by muse, mutect2, varscan2
- TBC1D4 | c.2088T>A p.L696= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as COSV100884537; called by muse, mutect2, varscan2
- TG | c.5121C>A p.P1707= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99599388; called by muse, mutect2, varscan2
- THNSL2 | c.540G>A p.T180= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as rs771757606, COSV100147338; called by muse, mutect2, varscan2
- TMEM97 | c.69C>A p.P23= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV99880609; called by muse, mutect2, varscan2
- USP53 | c.1374A>G p.L458= | Silent (SNP) | VAF 56/528 reads (11%) | catalogued as COSV99917539; called by muse, mutect2
- WDR41 | c.286T>C p.L96= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV99689096; called by muse, mutect2, varscan2
- WNK1 | c.7020G>C p.T2340= (on ENST00000315939 / NM_018979.4; = p.T2092= on NM_014823.3) | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV99942427; called by muse, mutect2, varscan2
